Somatic mutation profile of tumor specimen C3L-03632-02 (aliquot CPT0238440008) from CPTAC case C3L-03632, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G1; Age at diagnosis: 74.1 years (27,050 days).
Specimen C3L-03632-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) db73fca5-e829-4fe6-be0a-2445581214ef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-03632-31 (Blood Derived Normal), aliquot CPT0238470002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2dcc0366-d554-4447-8446-246c03ba30a7

The open-access MAF lists 26 somatic variants for this specimen: 13 protein-altering or splice-affecting, 10 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 10, 5'UTR 1, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 28/666 reads (4%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- ADGRL4 | c.229A>G p.N77D | Missense Mutation (SNP) | VAF 15/484 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV66061340; called by muse, mutect2
- HOXA6 | c.134C>T p.S45L | Missense Mutation (SNP) | VAF 39/920 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as rs765854235; called by muse, mutect2
- HOXD4 | c.79G>A p.G27S | Missense Mutation (SNP) | VAF 20/520 reads (4%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as COSV60459274; called by muse, mutect2
- KCNK9 | c.509C>T p.T170M | Missense Mutation (SNP) | VAF 57/1080 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57285819; called by muse, mutect2
- NAV3 | c.2006G>A p.C669Y | Missense Mutation (SNP) | VAF 18/288 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57094292; called by muse, mutect2
- TRPC7 | c.652C>T p.R218C | Missense Mutation (SNP) | VAF 11/201 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1192422925, COSV100725798; called by muse, mutect2
- CCDC159 | c.568A>G p.I190V | Missense Mutation (SNP) | VAF 9/225 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- EEF1A1 | c.791T>C p.V264A | Missense Mutation (SNP) | VAF 12/309 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.94); called by muse, mutect2
- INPP5D | c.2093C>T p.T698M (on ENST00000445964 / NM_001017915.3; = p.T697M on NM_005541.5) | Missense Mutation (SNP) | VAF 31/740 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- SLC5A12 | c.638T>C p.V213A | Missense Mutation (SNP) | VAF 20/418 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.12); called by muse, mutect2
- SUPT16H | c.626A>T p.D209V | Missense Mutation (SNP) | VAF 10/306 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2
- THEGL | c.1244C>A p.A415E | Missense Mutation (SNP) | VAF 16/351 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.908); called by muse, mutect2
- ALDH1L2 | c.27C>T p.L9= | Silent (SNP) | VAF 22/416 reads (5%) | catalogued as rs912352607; called by muse, mutect2
- GRWD1 | c.42G>A p.G14= | Silent (SNP) | VAF 81/634 reads (13%) | catalogued as rs1249590005; called by muse, mutect2, varscan2
- GRWD1 | c.774G>A p.V258= | Silent (SNP) | VAF 68/519 reads (13%) | catalogued as COSV53520239, COSV53520861; called by muse, mutect2, varscan2
- MCF2L | c.2802C>T p.A934= (on ENST00000375608; = p.A902= on NM_024979.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 37/857 reads (4%) | catalogued as rs370573668; called by muse, mutect2
- PCDHB15 | c.618C>T p.A206= | Silent (SNP) | VAF 22/580 reads (4%) | catalogued as rs1554291860, COSV99179124; called by muse, mutect2
- PEAK3 | c.1351C>T p.L451= | Silent (SNP) | VAF 14/367 reads (4%) | catalogued as COSV59233610; called by muse, mutect2
- THEGL | c.1245A>T p.A415= | Silent (SNP) | VAF 16/348 reads (5%) | called by muse, mutect2
- TRPC4 | c.762C>T p.D254= | Silent (SNP) | VAF 43/586 reads (7%) | called by muse, mutect2
- TTN | c.64707C>T p.Y21569= (on ENST00000591111; = p.Y14145= on NM_003319.4) | Silent (SNP) | VAF 50/1093 reads (5%) | catalogued as rs777602537, CM1514597, COSV100600284; ClinVar: likely benign; called by muse, mutect2
- USP6 | c.3846C>T p.G1282= | Silent (SNP) | VAF 36/1172 reads (3%) | catalogued as rs1319295998, COSV51485408; called by muse, mutect2
- NUDC | c.-16G>A | 5'UTR (SNP) | VAF 39/816 reads (5%) | catalogued as rs1393603860; called by muse, mutect2
- TSHZ2 | c.*1932A>G | 3'UTR (SNP) | VAF 42/1250 reads (3%) | called by muse, mutect2
- ZMYND8 | c.2605+204T>C | Intron (SNP) | VAF 7/123 reads (6%) | called by muse, mutect2
